Somatic mutation profile of tumor specimen 63a05d68-f0f7-42d9-a45f-df0f7e (aliquot 63a05d68-f0f7-42d9-a45f-df0f7e_D6_1) from CPTAC case 11BR030, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.5 years (18,462 days).
Specimen 63a05d68-f0f7-42d9-a45f-df0f7e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e356c596-3039-4e44-97ad-8b18596669ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2e1881a6-2228-4f07-883c-e25c6a (Blood Derived Normal), aliquot 2e1881a6-2228-4f07-883c-e25c6a_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5542aa0-087d-4b91-947e-acc9d20ea3e8

The open-access MAF lists 191 somatic variants for this specimen: 139 protein-altering or splice-affecting, 31 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 31, Intron 13, Nonsense Mutation 8, 5'Flank 3, 5'UTR 2, RNA 2, Splice Site 2, Splice Region 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- APC2 | c.650C>G p.S217W | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs565260681, COSV52018522, COSV52019339; called by muse, mutect2
- ARID2 | c.773-1G>C p.X258_splice | Splice Site (SNP) | VAF 9/179 reads (5%) | catalogued as COSV57600664, COSV57610982; called by muse, mutect2
- ATP8A1 | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as rs1022846322; called by muse, mutect2
- ATXN7 | c.1016G>C p.R339T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55748131; called by muse, mutect2
- BTN2A1 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as rs1328188500; called by muse, mutect2
- CDK5RAP3 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV58115806; called by muse, mutect2
- CIART | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV51743757; called by muse, mutect2
- COQ6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371260604, COSV99474165; called by muse, mutect2
- CPLANE1 | c.8754G>C p.K2918N | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV57068144; called by muse, mutect2, varscan2
- DDX55 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV53017884; called by muse, mutect2
- DGKD | c.1437C>G p.F479L (on ENST00000264057 / NM_152879.3; = p.F435L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51036227; called by muse, mutect2
- DHX32 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99501552; called by muse, mutect2
- DNAH11 | c.7314G>A p.M2438I | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1433773317; called by muse, mutect2
- FAM161A | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56766354; called by muse, mutect2
- FAM161B | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1330231223; called by muse, mutect2
- GABBR2 | c.359C>G p.A120G | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV52292175; called by muse, mutect2
- GJB2 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM112661; called by muse, mutect2
- GRB7 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 45/836 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV58446951; called by muse, mutect2
- H2AC20 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); catalogued as rs1553759886; called by muse, mutect2
- H2AC20 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV58611218; called by muse, mutect2
- HR | c.1543C>A p.Q515K | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as CM056336; called by muse, mutect2
- HUWE1 | c.7981G>C p.E2661Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53335778; called by muse, mutect2
- ICE2 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55030443; called by muse, mutect2, varscan2
- ITGA2 | c.2876C>G p.S959* | Nonsense Mutation (SNP) | VAF 8/263 reads (3%) | catalogued as COSV56859953; called by muse, mutect2
- JMJD6 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1325653364, COSV57971821, COSV57972254, COSV57972715; called by muse, mutect2, varscan2
- KLF4 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs1190671294, COSV101012688; called by muse, mutect2
- KLHL30 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV59978625; called by muse, mutect2
- LRP6 | c.3395C>G p.S1132* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | catalogued as COSV99743053; called by muse, mutect2
- M6PR | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs751187988; called by muse, mutect2, varscan2
- MBD1 | c.1645G>C p.E549Q (on ENST00000269468 / NM_001323950.1; = p.E447Q on NM_002384.2) | Missense Mutation (SNP) | VAF 29/620 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV53997625; called by muse, mutect2
- MITF | c.403C>T p.R135W (on ENST00000448226 / NM_006722.3; = p.R29W on NM_000248.4) | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200583343, COSV58836440; called by muse, mutect2
- MME | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV64708669; called by muse, mutect2
- NUP155 | c.3433G>C p.E1145Q (on ENST00000231498 / NM_153485.3; = p.E1086Q on NM_004298.4) | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51533619; called by muse, mutect2
- NUP62 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs1389217785, COSV61311921; called by muse, mutect2
- OR11H1 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1315802194, COSV53271283, COSV99421780; called by muse, mutect2
- PCNP | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.444); catalogued as rs1279025604; called by muse, mutect2
- PLCG2 | c.2187G>A p.M729I | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.983); catalogued as rs1160757509; called by muse, mutect2
- SOS2 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53567505; called by muse, mutect2
- USP32 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV56273080; called by muse, mutect2
- VLDLR | c.1942C>G p.L648V | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV101173203; called by muse, mutect2
- ZNF630 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.334); catalogued as COSV52095789; called by muse, mutect2, varscan2
- ZSWIM1 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 13/293 reads (4%) | catalogued as COSV99666468; called by muse, mutect2
- ADAMTSL4 | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGO2 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ALAS1 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- ALMS1 | c.5163C>G p.F1721L | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ALPK1 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- ARHGAP12 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); called by muse, mutect2
- ASCL2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ASH1L | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.899); called by muse, mutect2
- AWAT2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- C16orf96 | c.2887C>G p.L963V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- CACNA2D1 | c.2695G>C p.D899H (on ENST00000356253 / NM_001366867.1; = p.D887H on NM_000722.4) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- CD207 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CLTC | c.2941G>C p.E981Q | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COG7 | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2
- CTNNAL1 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CUL5 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); called by muse, mutect2
- CWC22 | c.703A>C p.K235Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DGAT1 | c.1161-6C>G | Splice Region (SNP) | VAF 15/322 reads (5%) | called by muse, mutect2
- DHX35 | c.1551C>G p.I517M | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DIAPH2 | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH11 | c.4545C>A p.F1515L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ECSIT | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2
- ERBB2 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 48/922 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- ERCC4 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- FAM50B | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAT4 | c.10709C>T p.T3570I | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBXO21 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.243); called by muse, mutect2
- FLG | c.3733G>C p.D1245H | Missense Mutation (SNP) | VAF 14/429 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- FYB1 | c.2226T>A p.D742E (on ENST00000351578 / NM_199335.5; = p.D788E on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2
- HADH | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2
- HMX3 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- HOOK3 | c.2131C>A p.H711N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.76); called by muse, mutect2
- HRC | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 17/313 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- HSD3B1 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- HSPA12A | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.09); called by muse, mutect2
- HSPB1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 18/620 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- HUWE1 | c.2802G>C p.L934F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- IGHA2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 27/426 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- INTS1 | c.3077A>T p.Y1026F | Missense Mutation (SNP) | VAF 28/580 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.125); called by muse, mutect2
- KMT2D | c.16543G>C p.D5515H | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAMA1 | c.3996G>C p.Q1332H | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); called by muse, mutect2
- LGALS9 | c.920C>T p.S307L (on ENST00000395473 / NM_009587.3; = p.S275L on NM_002308.4) | Missense Mutation (SNP) | VAF 30/846 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.027); called by muse, mutect2
- MEMO1 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MGAM2 | c.3236C>G p.S1079C | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MON1B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- MYH11 | c.3859-1G>C p.X1287_splice | Splice Site (SNP) | VAF 14/330 reads (4%) | called by muse, mutect2
- NAGA | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- NME1-NME2 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- NUDCD1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- OBSCN | c.22219G>C p.D7407H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2
- OR10H4 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PER2 | c.947G>C p.R316T | Missense Mutation (SNP) | VAF 23/614 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- PKHD1 | c.6523G>C p.E2175Q | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLCB4 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCE1 | c.5957G>C p.R1986T | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- PLEKHG3 | c.3144G>C p.K1048N (on ENST00000394691; = p.K1104N on NM_001308147.2) | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- PNISR | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); called by muse, mutect2
- PNPLA2 | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- POLRMT | c.1545G>C p.Q515H | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- POPDC3 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- POU6F2 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP6R1 | c.2309C>G p.S770C | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.339); called by muse, mutect2
- PROSER1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.038); called by muse, mutect2
- RC3H1 | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- RNF213 | c.7594G>C p.E2532Q | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2
- SEC23B | c.1965C>G p.F655L | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- SETDB1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- SFXN1 | c.230C>A p.S77* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- SH3BP2 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 11/323 reads (3%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- SH3GL2 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- SLC39A12 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- SLC9A9 | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SP3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 18/283 reads (6%) | called by muse, mutect2
- SPTB | c.4362G>C p.L1454F | Missense Mutation (SNP) | VAF 30/714 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- TAOK1 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2
- TASOR2 | c.6400G>C p.E2134Q | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TOPBP1 | c.2534C>A p.A845D | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- TOX2 | c.800G>C p.R267T (on ENST00000358131 / NM_001098798.2; = p.R216T on NM_032883.3) | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TP53 | c.348del p.T118Qfs*5 | Frame Shift Del (DEL) | VAF 18/174 reads (10%) | called by mutect2, pindel
- TRAPPC9 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TSLP | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.11); called by muse, mutect2
- TTBK1 | c.2064C>G p.F688L | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.111); called by muse, mutect2
- TTBK1 | c.2519C>G p.S840C | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TTN | c.41563G>T p.D13855Y (on ENST00000591111; = p.D6431Y on NM_003319.4) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UBL4A | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 8/264 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- VWCE | c.593T>G p.I198S | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- WNK1 | c.5630C>T p.S1877L (on ENST00000315939 / NM_018979.4; = p.S1629L on NM_014823.3) | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ZMPSTE24 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- ZNF121 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); called by muse, mutect2
- ZNF157 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ZNF197 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | called by muse, varscan2
- ZNF429 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ZNF524 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2
- ZNF526 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 26/632 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.357); called by muse, mutect2
- ZNF711 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 12/420 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- ZNF827 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ANPEP | c.1701C>G p.L567= | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- BRWD1 | c.5160A>C p.S1720= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- C9orf131 | c.180G>T p.G60= | Silent (SNP) | VAF 16/428 reads (4%) | called by muse, mutect2
- CBLB | c.2256G>A p.E752= | Silent (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- DMXL2 | c.291C>G p.L97= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV51847400; called by muse, mutect2, varscan2
- EHBP1 | c.1986G>A p.R662= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- FILIP1L | c.3054C>T p.R1018= (on ENST00000354552 / NM_182909.3; = p.R778= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/228 reads (6%) | catalogued as COSV100496881; called by muse, mutect2
- HLF | c.846G>A p.K282= | Silent (SNP) | VAF 48/325 reads (15%) | called by muse, varscan2
- HSF4 | c.516G>A p.V172= | Silent (SNP) | VAF 20/652 reads (3%) | catalogued as rs1203551197; called by muse, mutect2
- HSPB1 | c.603G>A p.E201= | Silent (SNP) | VAF 18/620 reads (3%) | called by muse, mutect2
- IGHMBP2 | c.1725G>C p.V575= | Silent (SNP) | VAF 26/726 reads (4%) | called by muse, mutect2
- ISLR | c.1170C>G p.L390= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as COSV51432807, COSV51435653; called by muse, mutect2
- LCTL | c.597C>T p.F199= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- LIG1 | c.1005C>G p.L335= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as COSV54392302, COSV54394318, COSV99074765; called by muse, mutect2
- LTBP3 | c.3471C>T p.L1157= (on ENST00000301873 / NM_001130144.3; = p.L1110= on NM_021070.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- MAPK8IP2 | c.2061C>T p.F687= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV50497449; called by muse, mutect2
- MUC16 | c.1941C>G p.V647= | Silent (SNP) | VAF 12/292 reads (4%) | catalogued as COSV101201772; called by muse, mutect2
- NHLRC1 | c.190C>T p.L64= | Silent (SNP) | VAF 40/476 reads (8%) | catalogued as COSV100513582; called by muse, mutect2
- OR2T34 | c.597C>G p.L199= | Silent (SNP) | VAF 14/327 reads (4%) | catalogued as COSV60899592; called by muse, mutect2
- PGAP6 | c.579C>T p.I193= | Silent (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- PHKG1 | c.1095G>A p.Q365= | Silent (SNP) | VAF 16/456 reads (4%) | called by muse, mutect2
- PLK5 | c.606C>G p.L202= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100598483; called by muse, mutect2
- SETX | c.7791G>C p.L2597= | Silent (SNP) | VAF 15/297 reads (5%) | called by muse, mutect2
- SI | c.4770G>A p.L1590= | Silent (SNP) | VAF 36/348 reads (10%) | called by muse, mutect2, varscan2
- SLC17A4 | c.1083C>G p.L361= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- SLC25A53 | c.90C>G p.A30= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- SLC28A1 | c.975G>A p.L325= | Silent (SNP) | VAF 32/611 reads (5%) | called by muse, mutect2
- TOP2B | c.4443G>A p.L1481= (on ENST00000264331 / NM_001330700.2; = p.L1476= on NM_001068.3) | Silent (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- UNC45A | c.2211C>T p.L737= | Silent (SNP) | VAF 23/239 reads (10%) | catalogued as rs548551634, COSV101263208; called by muse, mutect2
- VWF | c.6549C>G p.L2183= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as rs952110299; called by muse, mutect2
- ZFPM2 | c.3081G>T p.L1027= | Silent (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- AP000769.3 | chr11:65505373 G>C | 5'Flank (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- ATRX | c.5566+170C>G | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- BEND5 | c.-44C>T | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CHEK2 | c.1591-34G>C | Intron (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- DHX40P1 | n.704C>A | RNA (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- EGF | c.-39C>G | 5'UTR (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- ERCC4 | c.1213+48G>A | Intron (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- FOXA1 | c.72+754C>A | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- GPAT2 | c.2150-11C>G | Intron (SNP) | VAF 11/235 reads (5%) | called by muse, mutect2
- GTF2H3 | c.93+625C>G | Intron (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- IKBIP | c.297+7647G>C | Intron (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- ITIH5 | c.2032+787G>A | Intron (SNP) | VAF 8/164 reads (5%) | catalogued as COSV99905625; called by muse, mutect2
- KY | c.1090+167G>A | Intron (SNP) | VAF 11/249 reads (4%) | catalogued as rs916730392, COSV71016429, COSV71017933; called by muse, mutect2
- LPAR6 | c.*46C>G | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- PCGF2 | chr17:38749751 C>G | 5'Flank (SNP) | VAF 32/488 reads (7%) | called by muse, mutect2
- SLC19A3 | c.150+1050G>T | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- SSPOP | n.972C>T | RNA (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- SYNGR1 | c.100-10122C>G | Intron (SNP) | VAF 19/425 reads (4%) | called by muse, mutect2
- TNC | c.4579+4212C>G | Intron (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- TSPYL4 | chr6:116258638 C>T | 5'Flank (SNP) | VAF 43/650 reads (7%) | called by muse, mutect2
- WDR73 | c.518-35C>G | Intron (SNP) | VAF 18/388 reads (5%) | called by muse, mutect2
